Somatic mutation profile of tumor specimen TCGA-CR-5249-01A (aliquot TCGA-CR-5249-01A-01D-1512-08) from TCGA case TCGA-CR-5249, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 35.7 years (13,047 days).
Specimen TCGA-CR-5249-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 240d35e6-5086-47cd-8ba0-08125372a942.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-5249-10A (Blood Derived Normal), aliquot TCGA-CR-5249-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02af60a7-dd0e-43fd-913f-19652a9dd5b3

The open-access MAF lists 36 somatic variants for this specimen: 22 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 18, Silent 14, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 150/220 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2776G>A p.D926N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100751049; called by muse, mutect2, varscan2
- ABCG1 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100494442, COSV59202439; called by muse, mutect2
- CHD1 | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99399766; called by muse, mutect2, varscan2
- DNAH11 | c.558A>T p.Q186H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV100180331; called by mutect2, varscan2
- IGHV1-18 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs370195764; called by muse, mutect2, varscan2
- IQCG | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 31/1229 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs1194045881, COSV99502620; called by muse, mutect2
- KCNA4 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60254165; called by muse, mutect2, varscan2
- KCNB1 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV65565835; called by muse, mutect2, varscan2
- OR4A5 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.248); catalogued as rs760971695, COSV100157251; called by muse, mutect2, varscan2
- PCDH11X | c.3247C>G p.H1083D | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.449); catalogued as COSV100014354, COSV53512666; called by muse, mutect2, varscan2
- QTRT1 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs968107396, COSV99139095; called by muse, mutect2, varscan2
- SLC13A5 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.063); catalogued as rs1338244280, COSV99546128; called by muse, mutect2, varscan2
- SLC26A11 | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as rs1401469650, COSV100413570; called by muse, mutect2, varscan2
- SYNE1 | c.25258C>T p.R8420* (on ENST00000367255 / NM_182961.4; = p.R8372* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 29/122 reads (24%) | catalogued as rs752405799, COSV55129877; called by muse, mutect2, varscan2
- THAP9 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.151); catalogued as COSV100155966; called by muse, mutect2, varscan2
- TMEM202 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100499090; called by muse, mutect2, varscan2
- WDR44 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as rs763417168, COSV99561873; called by muse, mutect2, varscan2
- ERCC6L2 | c.3373C>G p.Q1125E | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HELLS | c.1405del p.Y469Mfs*16 | Frame Shift Del (DEL) | VAF 32/121 reads (26%) | called by mutect2, pindel, varscan2
- LAX1 | c.424_426del p.T142del | In Frame Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- PARD3 | c.31dup p.R11Pfs*52 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- C6orf58 | c.774A>G p.R258= | Silent (SNP) | VAF 73/231 reads (32%) | catalogued as rs753374472, COSV100315021; called by muse, mutect2, varscan2
- CACNA1A | c.4524C>A p.I1508= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs937843337, COSV100803083, COSV64211460; called by muse, mutect2, varscan2
- CHST6 | c.840G>A p.P280= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs1464704075, COSV59999839; called by muse, mutect2, varscan2
- DLX3 | c.471C>T p.P157= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs374399473; called by muse, varscan2
- HECTD1 | c.3657G>A p.G1219= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV101237475; called by muse, mutect2, varscan2
- ILF3 | c.1464G>A p.A488= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs755769030, COSV51556214; called by muse, mutect2
- MTCL1 | c.4782G>A p.E1594= (on ENST00000306329 / NM_001378206.1; = p.E1275= on NM_015210.4) | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100095381; called by muse, mutect2, varscan2
- PTPRE | c.2019G>A p.V673= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs774046953, COSV99618755; called by muse, mutect2, varscan2
- SAMD4A | c.339T>C p.I113= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as rs1488858817, COSV51882753; called by muse, mutect2, varscan2
- SC5D | c.708T>C p.F236= | Silent (SNP) | VAF 11/215 reads (5%) | catalogued as COSV99873182; called by muse, mutect2
- SLITRK3 | c.2133T>C p.D711= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV99579886; called by muse, mutect2, varscan2
- SNRNP200 | c.81C>T p.L27= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV60490570; called by muse, mutect2, varscan2
- WWP2 | c.801C>A p.P267= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV100598725; called by muse, mutect2, varscan2
- ZNF569 | c.1479C>A p.P493= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as COSV100386597; called by muse, mutect2, varscan2
